Somatic mutation profile of tumor specimen TCGA-FY-A3I5-01B (aliquot TCGA-FY-A3I5-01B-11D-A21Z-08) from TCGA case TCGA-FY-A3I5, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 64.8 years (23,654 days).
Specimen TCGA-FY-A3I5-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4cd83dce-9914-4583-a664-8ec82dd4f88e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FY-A3I5-10A (Blood Derived Normal), aliquot TCGA-FY-A3I5-10A-01D-A21Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e780788c-9be1-4e70-9206-5ff06888e1a4

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Nonsense Mutation 2, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DAAM1 | c.1579A>G p.I527V | Missense Mutation (SNP) | VAF 18/227 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747287197, COSV62835967; called by muse, mutect2
- EFCAB1 | c.160C>T p.R54* | Nonsense Mutation (SNP) | VAF 32/134 reads (24%) | catalogued as rs201706002, COSV100030541, COSV50617834; called by muse, mutect2, varscan2
- GBP2 | c.1088T>C p.I363T | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.609); catalogued as rs754899560, COSV65069167; called by muse, mutect2, varscan2
- RUNDC1 | c.802G>T p.E268* | Nonsense Mutation (SNP) | VAF 34/135 reads (25%) | catalogued as COSV64511779; called by muse, mutect2, varscan2
- TCHP | c.1412C>G p.A471G | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.084); catalogued as COSV57165403; called by muse, mutect2, varscan2
- VDAC1 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 65/310 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs375779223; called by muse, mutect2, varscan2
- ZNF521 | c.2800G>A p.V934M | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV64126214; called by muse, mutect2, varscan2
- ZW10 | c.408G>T p.Q136H | Missense Mutation (SNP) | VAF 101/378 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.421); catalogued as COSV52316254; called by muse, mutect2, varscan2
- SAMD15 | c.1336del p.R446Efs*6 | Frame Shift Del (DEL) | VAF 31/76 reads (41%) | called by mutect2, pindel, varscan2
- GALNT12 | c.945T>C p.F315= | Silent (SNP) | VAF 85/171 reads (50%) | catalogued as COSV66662617; called by muse, mutect2, varscan2
- PHKA1 | c.1413C>T p.I471= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV59805331; called by muse, mutect2, varscan2
